Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UC, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UC-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:
Retroperitoneal mass, leiomyosarcoma.

Specimens Submitted:
1: SP: Radical resection of caval leiomyosarcoma

DIAGNOSIS:

1. "CAVAL LEIOMYOSARCOMA", RADICAL RESECTION:
- HIGH GRADE LEIOMYOSARCOMA, WITH AREAS OF NECROSIS, INVOLVING A LARGE VEIN AND EXTENDING INTO THE SURROUNDING FIBROADIPOSE TISSUE.
- TUMOR SIZE: 7 X 4.5 X 4 CM.
- VEIN AND SOFT TISSUE SURGICAL MARGINS ARE NEGATIVE, HOWEVER, TUMOR IS <0.1 CM FROM THE POSTERIOR, 0.3 CM FROM THE MEDIAL AND 0.4 CM FROM THE ANTERIOR MARGINS OF RESECTION.
- ONE ADJACENT LYMPH NODE IS INVOLVED BY TUMOR. ADDITIONAL FOUR LYMPH NODES ARE NEGATIVE (0/4).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh, labeled "radical resection of caval leiomyosarcoma, short stitch - superior caval margin; long stitch lateral psoas muscle margin", consists of a 7 x 4.5 x 4 cm soft tissue mass covered predominately by a smooth glistening mobile serosal membrane. The lateral surface of the mass has attached skeletal muscle (3 x 2 x 1.5 cm) and a vessel (2 cm in length and 0.7 cm in diameter). The superior aspect has a 1.5 cm staple line. The specimen is inked as follows: superior - red; lateral - blue; anterior - black; posterior - green; inferior - yellow; medial - orange. Cross sections show a tan lobulated mass expanding the vessel at the lateral margin. The tumor is within 0.1 cm of all of the inked margins. TPS submitted.

** Continued on next page **

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site:

path: Vena cava, NOS C49.4
CCCP: Retroperitoneum C48.0

5-2-12
RO

[page 2 of 2]
SURGICAL

Page 2 of 2

Summary of sections:

VM - vascular margin

CX - cross section of tumor mass

AM - anterior margin

PM - posterior margin

Summary of Sections:

Part 1: SP: Radical resection of caval leiomyosarcoma

Block	Sect.	Site	PCs
1		AM	1
1		CX	1
1		PM	1
1		VM	1

** End of Report **

Source: NCI Genomic Data Commons file 78411c6c-1e42-4ae1-a2c7-78215b4aa322 (TCGA-DX-A3UC.0458156D-0DBB-4B59-BFD2-8EAB378AF19E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).